Gene-level copy-number profile of tumor specimen TCGA-EY-A1G8-01A from TCGA case TCGA-EY-A1G8, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 83.6 years (30,517 days).
Specimen TCGA-EY-A1G8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.b828f9c8-06b7-4115-8266-3c5ed53db749.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EY-A1G8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 398 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d4c682e0-b2e1-4c66-b373-765fec2f500f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 522; copy number 1: 29; copy number 2: 57,077; copy number 3: 2,494; copy number 4: 5; copy number 5: 96; copy number 6: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-EY-A1G8-01): tumor purity 0.76, ploidy 2.05, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:61,581,813–61,627,683, 2 genes: AL935212.3, FAM242D.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 98 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:18,933,813–18,939,721, 2 genes, copy number 6: MRGPRX1, AC023078.1.
- chr14:105,764,503–106,335,613, 96 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 29. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
